Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5725, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5725-01A (Primary Tumor).

*** Diagnosis(es): ***

Total gastrectomy specimen with an ulcerated carcinoma of the esophagogastric junction of maximum diameter 6.5 cm localized subcardially in the area of the posterior wall on the greater curvature side, of the histological type of a poorly differentiated adenocarcinoma. Invasive tumor dissemination within all gastric wall layers as far as the adjacent perigastric fatty tissue and with lymphatic tumor spread.

Oral and aboral resection margin and greater omentum tumor-free.

Antrum and corpus with non-florid, moderate chronic gastritis, foveolar hyperplasia and focal intestinal metaplasia, and partial mucosal atrophy. No evidence of *Helicobacter pylori*. Twenty-four regional lymph nodes tumor-free with uncharacteristically reactive changes.

Therefore tumor stage pT2b pN0 (0/23)

Source: NCI Genomic Data Commons file 7baa8712-c033-4d4f-b495-572b4d659deb (TCGA-CG-5725.C7C5DEAC-897C-4F52-98F2-720567515B85.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).